CCDI case PBBPWT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6d96e877-c693-4155-9a69-f297c3ea4843

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,448 days).

Biospecimens (3 samples)
- Sample 0DEFHP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEFJB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEFJT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
